Somatic mutation profile of tumor specimen TCGA-ET-A3DO-01A (aliquot TCGA-ET-A3DO-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.3 years (12,158 days).
Specimen TCGA-ET-A3DO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b32858f-4345-4ce1-a96d-d3b8220cb740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DO-10A (Blood Derived Normal), aliquot TCGA-ET-A3DO-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018a5ef0-94dc-410d-82a2-019da78ec3ac

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- ADGRV1 | c.12940G>A p.D4314N | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67986974; called by muse, mutect2
- CGNL1 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55569425; called by muse, mutect2
- DCX | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57570523; called by muse, mutect2
- KRTAP10-11 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58178149; called by muse, mutect2
- LIG4 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV63597213; called by muse, mutect2, varscan2
- MAGEA1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV63118710; called by muse, mutect2, varscan2
- NFIA | c.581C>G p.P194R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64538621; called by muse, mutect2, varscan2
- SLC25A43 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV54218110; called by muse, varscan2
- TAS1R3 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59563797; called by muse, mutect2
- TENM1 | c.3392C>T p.S1131F | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64433865; called by muse, mutect2
- TTN | c.46630G>C p.E15544Q (on ENST00000591111; = p.E8120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/340 reads (3%) | PolyPhen probably damaging (0.997); catalogued as COSV60114606; called by muse, mutect2
- ANAPC5 | c.1062A>G p.R354= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs782488179; called by muse, mutect2
- NLRP4 | c.252C>T p.L84= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV56715453; called by muse, mutect2
- ZNF436 | c.-258A>T | 5'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
